Gene-level copy-number profile of tumor specimen TCGA-F7-A61V-01A from TCGA case TCGA-F7-A61V, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Base of tongue, NOS; AJCC pathologic stage: Stage II; Tumor grade: G1; Age at diagnosis: 54.4 years (19,857 days).
Specimen TCGA-F7-A61V-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-HNSC.3127fe70-9241-4956-a085-39023a3eef4b.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-F7-A61V-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 806 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/3e123791-723f-40e2-8803-ec607316f50d

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 2; copy number 1: 7,590; copy number 2: 47,942; copy number 3: 3,267; copy number 4: 368; copy number 5: 570; copy number 6: 72; copy number 8: 6.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-F7-A61V-01A-11D-A28Q-01): tumor purity 0.58, ploidy 2.01, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 2 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:141,167,257–141,208,376, 2 genes: RNU6-904P, RPS16P3.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 648 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:83,953,639–84,947,061, 5 genes, copy number 8: AC117464.1, LINC00971, AC117482.1, LINC02025, AC132660.2.
- chr3:85,385,710–85,385,792, 1 gene, copy number 8: MIR5688.
- chr3:165,772,904–198,222,513, 629 genes, copy number 5–6 (broad region; genes not listed).
- chr5:57,890,327–58,863,414, 13 genes, copy number 5: LINC02225, LINC02101, AC008786.1, PGAM1P1, PLK2, GAPT, AC008814.1, MIR548AE2, LINC02108, RAB3C, AC016642.1, RPL5P15, AC008852.1.

Autosomal genes at a single copy (total copy number 1): 5,203. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
